Somatic mutation profile of tumor specimen MP2PRT-PAVHRB-TMP1-A (aliquot MP2PRT-PAVHRB-TMP1-A-1-0-D-A83Q-36) from MP2PRT case MP2PRT-PAVHRB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.2 years (811 days).
Specimen MP2PRT-PAVHRB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) edb96306-4b36-4361-83eb-7e628d09d3e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVHRB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVHRB-NB1-A-1-0-D-A83Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7dc0695-33f1-4876-a9eb-745a18bb24d9

The open-access MAF lists 23 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 6, Nonsense Mutation 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PDE6B | c.2395C>T p.R799* | Nonsense Mutation (SNP) | VAF 69/215 reads (32%) | catalogued as rs970990957; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AEBP2 | c.1252C>G p.H418D | Missense Mutation (SNP) | VAF 24/317 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV56862781; called by muse, mutect2
- FSIP2 | c.638G>C p.R213T | Missense Mutation (SNP) | VAF 18/314 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV58099247; called by muse, mutect2
- H3C7 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 26/490 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV55101191; called by muse, mutect2
- P4HTM | c.583C>T p.R195W | Missense Mutation (SNP) | VAF 110/335 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as rs748444950, COSV100637602, COSV59086885; called by muse, mutect2, varscan2
- RASGRF1 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 102/315 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1166184207, COSV69177458; called by muse, mutect2, varscan2
- ZFP69B | c.1559G>C p.R520T | Missense Mutation (SNP) | VAF 12/367 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV64315426; called by muse, mutect2
- AC008676.3 | c.405C>G p.F135L | Missense Mutation (SNP) | VAF 24/497 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.066); called by muse, mutect2
- AC069544.2 | c.37T>C p.S13P | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.779); called by muse, mutect2
- ADNP2 | c.2079G>T p.W693C | Missense Mutation (SNP) | VAF 26/452 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL4A6 | c.3158G>C p.R1053T | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.042); called by muse, mutect2
- GDF2 | c.510_516dup p.Y173Gfs*4 | Frame Shift Ins (INS) | VAF 72/310 reads (23%) | called by mutect2, varscan2
- MARCHF10 | c.328A>T p.S110C | Missense Mutation (SNP) | VAF 28/334 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); called by muse, mutect2
- RB1CC1 | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 27/345 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.038); called by muse, mutect2
- RIBC2 | c.133G>C p.D45H | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- ZSCAN5B | c.92C>T p.T31I | Missense Mutation (SNP) | VAF 32/379 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.265); called by muse, mutect2
- ADGRF2 | c.1752T>A p.P584= (on ENST00000296862 / NM_001368115.2; = p.P516= on NM_153839.7) | Silent (SNP) | VAF 75/261 reads (29%) | called by muse, mutect2, varscan2
- DOCK3 | c.2929C>T p.L977= | Silent (SNP) | VAF 10/314 reads (3%) | called by muse, mutect2
- GALNT16 | c.615C>T p.T205= | Silent (SNP) | VAF 99/348 reads (28%) | catalogued as rs144789007; called by muse, mutect2, varscan2
- GPR137B | c.723C>T p.V241= | Silent (SNP) | VAF 19/374 reads (5%) | called by muse, mutect2
- NUDT2 | c.321C>T p.L107= | Silent (SNP) | VAF 24/467 reads (5%) | catalogued as rs748007466, COSV100663591; called by muse, mutect2
- TNFSF10 | c.621C>G p.V207= | Silent (SNP) | VAF 23/278 reads (8%) | called by muse, mutect2
- IER3 | c.210+25C>T | Intron (SNP) | VAF 34/756 reads (4%) | called by muse, mutect2
